Somatic mutation profile of tumor specimen TCGA-HD-7754-01A (aliquot TCGA-HD-7754-01A-11D-2078-08) from TCGA case TCGA-HD-7754, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 69.4 years (25,365 days).
Specimen TCGA-HD-7754-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7e57539-d096-42a4-bb80-c6be26c8c778.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-7754-10A (Blood Derived Normal), aliquot TCGA-HD-7754-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f48baeff-15db-4d58-a4c9-538bda840b5f

The open-access MAF lists 66 somatic variants for this specimen: 45 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 39, Silent 21, Splice Site 4, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGK | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100814742; called by muse, mutect2, varscan2
- AGL | c.2299T>C p.C767R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs749372877; called by muse, mutect2
- AGTR1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs56257794, COSV62557506; called by muse, mutect2, varscan2
- ATRX | c.4774C>T p.L1592F | Missense Mutation (SNP) | VAF 61/84 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100971599; called by muse, mutect2, varscan2
- BCAN | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs748416928, COSV100227782; called by muse, mutect2, varscan2
- BSCL2 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs916916343, COSV54014886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASZ1 | c.1501-1G>T p.X501_splice | Splice Site (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100681388, COSV100682290; called by muse, mutect2, varscan2
- CATSPER2 | c.842+1G>A p.X281_splice | Splice Site (SNP) | VAF 23/41 reads (56%) | catalogued as rs199516208, COSV58660954, COSV58661550; called by muse, mutect2, varscan2
- CDC37 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs750412756, COSV55768686; called by muse, mutect2, varscan2
- CRYBA4 | c.296G>T p.C99F | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV61323189; called by muse, mutect2
- DEPP1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs188702994, COSV53574317; called by muse, mutect2, varscan2
- DEPTOR | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.194); catalogued as COSV53817231; called by muse, mutect2, varscan2
- DHX37 | c.2428C>T p.R810W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762459392, COSV100439583; called by muse, mutect2, varscan2
- DIP2A | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV59471609; called by muse, mutect2, varscan2
- DNAH3 | c.6692A>G p.H2231R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771178171, COSV99771208; called by muse, mutect2, varscan2
- DNAI3 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99642528; called by muse, mutect2, varscan2
- EPPK1 | c.6038C>T p.T2013M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs571579347, COSV101599980; called by muse, mutect2, varscan2
- GC | c.647C>A p.S216* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV99910232; called by muse, mutect2, varscan2
- GJB3 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs761320902, COSV64904396; called by muse, mutect2, varscan2
- JAK2 | c.1214+1G>A p.X405_splice | Splice Site (SNP) | VAF 11/17 reads (65%) | catalogued as rs1471795147, COSV67632305, COSV99061304; called by muse, mutect2, varscan2
- KANSL1L | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs866709373, COSV99911042, COSV99911097; called by muse, mutect2, varscan2
- KIAA1549 | c.3457G>A p.E1153K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99652310; called by muse, mutect2, varscan2
- KRT40 | c.1097A>T p.E366V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1474308833, COSV100898920; called by muse, mutect2, varscan2
- LRP1B | c.12384A>G p.I4128M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101262057; called by muse, mutect2, varscan2
- MAPK6 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.926); catalogued as rs754697688, COSV55928582, COSV99959523; called by muse, mutect2, varscan2
- NCAPH2 | c.1359G>T p.R453S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.038); catalogued as COSV99329868; called by muse, mutect2, varscan2
- NFIL3 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as rs34945709; called by muse, mutect2, varscan2
- NPR3 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.159); catalogued as rs1263370705, COSV99423990; called by muse, mutect2, varscan2
- PDE4B | c.1888T>C p.W630R | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100305509; called by muse, mutect2, varscan2
- POLR2B | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs376895637; called by muse, mutect2, varscan2
- RARG | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58433492; called by muse, mutect2, varscan2
- RBX1 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99345505; called by muse, mutect2, varscan2
- SCEL | c.983A>G p.Q328R (on ENST00000349847 / NM_144777.3; = p.Q308R on NM_003843.4) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV100583302; called by muse, mutect2, varscan2
- SLC23A2 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57771376; called by muse, mutect2, varscan2
- SLC5A9 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377226169, COSV99361343; called by muse, mutect2, varscan2
- TAX1BP1 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs377033381; called by muse, mutect2, varscan2
- TMEM184A | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs778671985, COSV99869034; called by muse, mutect2, varscan2
- TMEM62 | c.1214A>G p.H405R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV99543924; called by muse, mutect2, varscan2
- TSHZ3 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.968); catalogued as rs369463125, COSV53662985, COSV53685530; called by muse, mutect2, varscan2
- TTN | c.1921C>A p.Q641K (on ENST00000591111; = p.Q595K on NM_003319.4) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | PolyPhen benign (0.022); catalogued as COSV100634288; called by muse, mutect2, varscan2
- VCAN | c.5929T>C p.S1977P | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99427653; called by muse, mutect2, varscan2
- ZMYM5 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs1194625882, COSV61988022; called by muse, mutect2, varscan2
- WDPCP | c.1625-1_1626del p.X542_splice | Splice Site (DEL) | VAF 23/61 reads (38%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.221dup p.P75Afs*50 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- ACTN2 | c.1602C>T p.G534= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs754706827, COSV63973841; called by muse, mutect2, varscan2
- ADAMTS8 | c.2433C>T p.D811= | Silent (SNP) | VAF 62/179 reads (35%) | catalogued as rs1438475664, COSV99960661, COSV99961703; called by muse, mutect2, varscan2
- AKAP6 | c.5142G>A p.S1714= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs1178024502, COSV55206312; called by muse, mutect2, varscan2
- ANO5 | c.1419C>T p.V473= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs201501021, COSV61083238; called by muse, mutect2, varscan2
- ARFGEF2 | c.309C>T p.N103= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs756761377, COSV64215919; called by muse, mutect2, varscan2
- BCAS1 | c.1479G>A p.Q493= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs756128339, COSV101006511; called by muse, mutect2, varscan2
- CACNA2D2 | c.732A>G p.T244= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV99818490; called by muse, mutect2, varscan2
- CACNG3 | c.414G>A p.A138= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs1430773509, COSV50067718; called by muse, mutect2, varscan2
- DYRK1A | c.657C>T p.Y219= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs746177928, COSV100118376; called by muse, mutect2, varscan2
- KAT14 | c.2131A>C p.R711= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs1398922941, COSV100890124; called by muse, mutect2, varscan2
- KIAA1109 | c.6279T>C p.V2093= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV99186985; called by muse, mutect2
- NPC1 | c.684C>T p.D228= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs558452690, COSV99342092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10X1 | c.492T>G p.A164= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV63767018, COSV63768118; called by muse, mutect2, varscan2
- OXTR | c.939C>T p.I313= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs748383989, COSV57478227; called by muse, mutect2, varscan2
- PI4K2B | c.678A>G p.K226= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV99335680; called by muse, mutect2, varscan2
- RUSF1 | c.519C>T p.D173= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs372035715; called by muse, mutect2, varscan2
- SEMA4A | c.741C>T p.F247= | Silent (SNP) | VAF 59/224 reads (26%) | catalogued as COSV100740754; called by muse, mutect2, varscan2
- SPSB2 | c.642C>T p.I214= | Silent (SNP) | VAF 159/281 reads (57%) | catalogued as COSV99222930, COSV99223009; called by muse, mutect2, varscan2
- SPTBN5 | c.3813C>T p.G1271= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs769680202, COSV100312375; called by muse, mutect2, varscan2
- TACC2 | c.6519G>A p.T2173= (on ENST00000334433; = p.T251= on NM_006997.4) | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as rs759521622, COSV53278171; called by muse, mutect2, varscan2
- TLR10 | c.579G>T p.L193= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV58300161; called by muse, mutect2, varscan2
